Somatic mutation profile of tumor specimen TARGET-10-PAPNNX-03A (aliquot TARGET-10-PAPNNX-03A-01D) from TARGET case TARGET-10-PAPNNX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.0 years (5,486 days).
Specimen TARGET-10-PAPNNX-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a00a886-0180-4325-9dbe-22ad46d1225f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPNNX-10A (Blood Derived Normal), aliquot TARGET-10-PAPNNX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bd0861c-abd8-457c-8d45-ddf6938f3d70

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Frame Shift Ins 4, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 39/311 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 87/400 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 298/810 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394549289, COSV53236562, COSV53247358; called by muse, mutect2, varscan2
- PLEKHG3 | c.1522G>A p.V508M (on ENST00000394691; = p.V564M on NM_001308147.2) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs775037199, COSV55982517; called by muse, mutect2, varscan2
- TBC1D22A | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 61/603 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61443632; called by muse, mutect2, varscan2
- ZFR2 | c.2020G>T p.V674L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53601840, COSV53602069; called by muse, mutect2, varscan2
- ZNF22 | c.671delinsCCC p.R224Pfs*8 | Frame Shift Ins (INS) | VAF 29/100 reads (29%) | catalogued as COSV53584526; called by pindel, varscan2*
- IGHV1-46 | c.349_350insCCCTGGG p.R117Tfs*? | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by mutect2, pindel
- KMT2D | c.1143dup p.T382Hfs*2 | Frame Shift Ins (INS) | VAF 9/77 reads (12%) | called by mutect2, pindel
- KMT2D | c.508_509del p.Q170Afs*49 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by pindel, varscan2
- LHFPL4 | c.182del p.L61Pfs*45 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- PPP3CC | c.1216_1217insGGTCGGAC p.I406Rfs*13 | Frame Shift Ins (INS) | VAF 114/478 reads (24%) | called by mutect2, pindel, varscan2
- UBA2 | c.774_777del p.F259Kfs*8 | Frame Shift Del (DEL) | VAF 81/467 reads (17%) | called by pindel*, varscan2
- ADGRG6 | c.2655A>G p.T885= | Silent (SNP) | VAF 220/631 reads (35%) | catalogued as rs376656716; called by muse, mutect2
- MMP13 | c.771C>T p.D257= | Silent (SNP) | VAF 105/337 reads (31%) | catalogued as rs150719050; called by muse, mutect2, varscan2
- NAV2 | c.7338G>A p.P2446= (on ENST00000396087 / NM_001244963.2; = p.P2387= on NM_145117.5) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs771893645, COSV60663236; called by muse, mutect2, varscan2
- TRPC5 | c.1554C>A p.L518= | Silent (SNP) | VAF 47/162 reads (29%) | catalogued as COSV53291108, COSV53299210, COSV99461393; called by muse, mutect2, varscan2
